ALCHEMIST case ALCH-B2DN — Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial (ALCHEMIST-ALCH)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026).
https://portal.gdc.cancer.gov/cases/1254448d-c18c-4796-a667-1a449feb5c49

Demographics
Sex at birth: male.

Diagnoses (1)
1. Adenocarcinoma, NOS: Age at diagnosis: 72.5 years (26,474 days).

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ALCH-B2DN-NB1-A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Fresh.
- Sample ALCH-B2DN-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ALCH-B2DN-TTP1-A-1-0-S1: Section location: Top; Percent tumor cells: 72; Percent tumor nuclei: 70; Percent normal cells: 20; Percent necrosis: 8; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample ALCH-B2DN-TTR1-A: Sample type: FFPE Recurrent; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ALCH-B2DN-TTR1-A-1-0-S1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 60; Percent normal cells: 10; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
